Somatic mutation profile of tumor specimen 0DW8GQ from CCDI case PBCJUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.9 years (3,978 days).
Specimen 0DW8GQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed58574-d8c8-4cc0-aa89-d910274937dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW8GG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/688469c9-72d7-4440-b90a-1ef59eb90180

The open-access MAF lists 3 somatic variants for this specimen: 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APTX | c.*85C>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- CCDC96 | c.*75C>A | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as rs1245205038, COSV100028142; called by muse, mutect2
- SOGA1 | c.*8748T>C | 3'UTR (SNP) | VAF 52/121 reads (43%) | called by muse, mutect2, varscan2
